Somatic mutation profile of tumor specimen C3L-09561-03 (aliquot CPT0515950006) from CPTAC case C3L-09561, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 68.2 years (24,907 days).
Specimen C3L-09561-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2741489c-7d42-4623-ae97-456eca3c7653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09561-31 (Blood Derived Normal), aliquot CPT0516020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee4dcab5-02fc-4ed0-8b02-a79d00df2184

The open-access MAF lists 96 somatic variants for this specimen: 76 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 17, Nonsense Mutation 6, Frame Shift Del 5, Intron 2, RNA 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 123/281 reads (44%) | catalogued as rs1114167559, CM105838, COSV57381203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 134/233 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGDIA | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 170/483 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV53907865; called by muse, mutect2, varscan2
- CHRM3 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 108/291 reads (37%) | catalogued as COSV99698050; called by muse, mutect2, varscan2
- CMPK2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs754020979, COSV56774556; called by muse, mutect2, varscan2
- EPN3 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1458389741; called by muse, mutect2, varscan2
- FMN2 | c.1283C>G p.S428W | Missense Mutation (SNP) | VAF 78/413 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100147729; called by muse, mutect2, varscan2
- GRXCR1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs753832546, COSV67672722; called by muse, varscan2
- HK2 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 136/340 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV99308790; called by muse, mutect2, varscan2
- HTR5A | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs758761162, COSV55284225; called by muse, mutect2, varscan2
- HUS1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 133/397 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs761731324; called by muse, mutect2, varscan2
- IGKV2D-24 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1173345620; called by muse, mutect2, varscan2
- KIAA1549 | c.5833G>A p.V1945M (on ENST00000422774 / NM_001164665.2; = p.V1929M on NM_020910.3) | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs370670659; called by muse, mutect2, varscan2
- KRTAP19-3 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.304); catalogued as COSV61854593, COSV61855062; called by muse, mutect2, varscan2
- L3MBTL3 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199384342, COSV62384840; called by muse, mutect2, varscan2
- LAMA1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs748409752; called by muse, mutect2, varscan2
- LRP1B | c.9313G>C p.D3105H | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67222435; called by muse, mutect2, varscan2
- MAP2K7 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 121/252 reads (48%) | catalogued as COSV67608904; called by muse, mutect2, varscan2
- MAP3K2 | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs1329308319; called by muse, mutect2, varscan2
- MTERF4 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV54087975; called by muse, mutect2, varscan2
- NIN | c.4673C>T p.T1558M (on ENST00000382041 / NM_182946.1; = p.T845M on NM_016350.4) | Missense Mutation (SNP) | VAF 34/686 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs776474311, COSV55381771; called by muse, mutect2
- NLRP4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs750811265, COSV56722494; called by muse, mutect2, varscan2
- NOVA1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57473964; called by muse, mutect2, varscan2
- PALLD | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 157/313 reads (50%) | catalogued as rs1166557733, COSV54978776, COSV54980826; called by muse, mutect2, varscan2
- PCDH18 | c.1991C>A p.P664H | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100787449; called by muse, mutect2, varscan2
- PCSK9 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1272068040; called by muse, mutect2, varscan2
- PDHA2 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1387915585; called by muse, mutect2, varscan2
- PIGV | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 153/292 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs1320617918, COSV50292416; called by muse, mutect2, varscan2
- PIP5K1B | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 139/295 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV55251737; called by muse, mutect2, varscan2
- REV1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs72550807; called by muse, mutect2, varscan2
- RGS9 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 97/365 reads (27%) | catalogued as rs866271704; called by muse, mutect2, varscan2
- RORC | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427978992, COSV100561782; called by muse, mutect2, varscan2
- SLC38A10 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs765530635; called by muse, mutect2, varscan2
- SPSB1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 151/429 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as rs766691929, COSV60163070; called by muse, mutect2, varscan2
- SYNPO | c.1972G>A p.V658I (on ENST00000394243 / NM_001166208.2; = p.V414I on NM_007286.6) | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs955709297; called by muse, mutect2, varscan2
- TBCD | c.1536C>A p.A512= | Splice Region (SNP) | VAF 95/311 reads (31%) | catalogued as COSV100832725, COSV62801224; called by muse, mutect2, varscan2
- TDRD15 | c.4430A>T p.K1477M | Missense Mutation (SNP) | VAF 149/270 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV68267509; called by muse, mutect2, varscan2
- TMC6 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1334699503; called by muse, varscan2
- TNNT3 | c.278G>A p.R93Q (on ENST00000397301 / NM_001367846.1; = p.R82Q on NM_006757.4) | Missense Mutation (SNP) | VAF 132/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415991336; called by muse, mutect2, varscan2
- TP53 | c.290del p.V97Afs*26 | Frame Shift Del (DEL) | VAF 159/416 reads (38%) | catalogued as COSV53188034, COSV99378755; called by mutect2, pindel, varscan2
- WNT2B | c.775C>T p.R259C (on ENST00000369684 / NM_024494.3; = p.R240C on NM_004185.4) | Missense Mutation (SNP) | VAF 142/299 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201153849, COSV56675972; called by muse, mutect2, varscan2
- ZGLP1 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 207/399 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1256738093, COSV58533265; called by muse, mutect2, varscan2
- AHNAK2 | c.1489del p.S497Pfs*31 | Frame Shift Del (DEL) | VAF 155/448 reads (35%) | called by mutect2, pindel, varscan2
- AP5M1 | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf52 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPRIN2 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CEP170B | c.4547C>T p.P1516L (on ENST00000453495; = p.P1445L on NM_015005.3) | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CIAO1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL13A1 | c.2154A>G p.*718Wext*3 (on ENST00000398978 / NM_001130103.2; = p.*646Wext*3 on NM_080798.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 107/208 reads (51%) | called by muse, mutect2, varscan2
- DNAH8 | c.3790G>A p.D1264N | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM133A | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 92/149 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GOLGA3 | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- GP1BB | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 128/430 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- HTR2B | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IER5 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 203/541 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- IVL | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 176/519 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JMJD1C | c.1685A>T p.D562V | Missense Mutation (SNP) | VAF 129/266 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- KIAA0100 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 124/359 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- LRCH2 | c.1228A>C p.N410H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL50 | c.356_398del p.Q119Lfs*20 | Frame Shift Del (DEL) | VAF 55/287 reads (19%) | called by mutect2, pindel, varscan2
- MYO9B | c.5888A>G p.K1963R | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NRK | c.4066A>C p.I1356L | Missense Mutation (SNP) | VAF 80/125 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR1D5 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- OTOG | c.6448G>T p.V2150L | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- POGZ | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 59/345 reads (17%) | called by muse, mutect2, varscan2
- POU3F3 | c.321_357del p.A108Rfs*30 | Frame Shift Del (DEL) | VAF 109/530 reads (21%) | called by mutect2, pindel, varscan2
- SHC1 | c.994T>G p.F332V (on ENST00000368445 / NM_183001.5; = p.F222V on NM_003029.5) | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SNAI2 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 158/373 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM64C | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 158/527 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TTC30A | c.1528A>C p.M510L | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TUT4 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UNC5B | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 175/387 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP34 | c.327_330del p.R109Sfs*13 | Frame Shift Del (DEL) | VAF 105/343 reads (31%) | called by mutect2, pindel, varscan2
- ZNF536 | c.2098G>T p.V700F | Missense Mutation (SNP) | VAF 162/373 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF544 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AMN | c.783C>T p.H261= | Silent (SNP) | VAF 51/327 reads (16%) | catalogued as rs368430211; called by muse, mutect2, varscan2
- CDH10 | c.2265T>C p.T755= | Silent (SNP) | VAF 44/480 reads (9%) | catalogued as rs867492413; called by muse, mutect2
- CDH10 | c.936C>T p.D312= | Silent (SNP) | VAF 123/519 reads (24%) | catalogued as rs1021736142, COSV52574806, COSV52583443; called by muse, mutect2, varscan2
- DSPP | c.3192C>T p.S1064= | Silent (SNP) | VAF 171/534 reads (32%) | catalogued as rs752142795, COSV56808997; called by muse, varscan2
- FAM120C | c.591C>T p.I197= | Silent (SNP) | VAF 196/295 reads (66%) | catalogued as rs1048186657; called by muse, mutect2, varscan2
- FAT3 | c.4257A>G p.K1419= | Silent (SNP) | VAF 38/320 reads (12%) | called by muse, mutect2, varscan2
- GPRC5B | c.507G>A p.L169= | Silent (SNP) | VAF 175/509 reads (34%) | called by muse, mutect2, varscan2
- KIF3C | c.732C>T p.L244= | Silent (SNP) | VAF 225/442 reads (51%) | catalogued as rs754940424; called by muse, mutect2, varscan2
- NKX1-1 | c.387G>A p.P129= | Silent (SNP) | VAF 102/498 reads (20%) | called by muse, mutect2, varscan2
- OR4C15 | c.346T>C p.L116= (on ENST00000314644; = p.L62= on NM_001001920.2) | Silent (SNP) | VAF 117/408 reads (29%) | catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2, varscan2
- P2RY2 | c.261G>A p.P87= | Silent (SNP) | VAF 120/427 reads (28%) | called by muse, mutect2, varscan2
- PCDH17 | c.333C>T p.N111= | Silent (SNP) | VAF 65/460 reads (14%) | catalogued as rs1363153167, COSV64972520; called by muse, mutect2, varscan2
- PRPS2 | c.951G>A p.P317= | Silent (SNP) | VAF 15/167 reads (9%) | catalogued as COSV66180363; called by muse, mutect2
- STX16 | c.723C>T p.R241= (on ENST00000371141 / NM_001001433.3; = p.R220= on NM_003763.6) | Silent (SNP) | VAF 143/351 reads (41%) | called by muse, mutect2, varscan2
- UBE3A | c.1861C>T p.L621= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- UNC80 | c.759G>A p.R253= | Silent (SNP) | VAF 88/270 reads (33%) | called by muse, mutect2, varscan2
- ZGPAT | c.291T>C p.R97= | Silent (SNP) | VAF 83/509 reads (16%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+20718T>G | Intron (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- LAMA4 | c.195+26C>T | Intron (SNP) | VAF 135/318 reads (42%) | called by muse, mutect2, varscan2
- NBPF25P | n.971G>C | RNA (SNP) | VAF 53/345 reads (15%) | called by muse, mutect2, varscan2
